Gene-level copy-number profile of tumor specimen TCGA-EJ-5525-01A from TCGA case TCGA-EJ-5525, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 67.2 years (24,535 days).
Specimen TCGA-EJ-5525-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.aa4f47e0-9c04-466a-9402-b972ee88e98e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EJ-5525-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/14d3fc30-78eb-4c4f-8626-250470e33895

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,324; copy number 2: 45,148; copy number 3: 3,372; copy number 4: 1,113; copy number 5: 1,863.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EJ-5525-01A-01D-1574-01): tumor purity 0.87, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,863 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:116,671,749–121,580,524, 113 genes, copy number 5 (broad region; genes not listed).
- chr8:40,104,169–145,066,685, 1,624 genes, copy number 5 (broad region; genes not listed).
- chr15:94,583,506–98,420,998, 66 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr21:38,380,027–41,459,214, 60 genes, copy number 5 (within-gene range 2–5): ERG, SNRPGP13, AP001037.1, LINC00114, ETS2, AP001042.1, AP001042.2, AP001042.3, AP001043.1, SNORA62, RPSAP64, LINC01700, AF064858.1, AF064858.3, AF064858.2, RPL23AP12, PCBP2P1, AF129408.2, PSMG1, BRWD1, AF129408.1, TIMM9P2, BRWD1-IT1, METTL21AP1, BRWD1-AS2, BRWD1-AS1, HMGN1, Y_RNA, RNF6P1, GET1, GET1-SH3BGR, LCA5L, SH3BGR, MIR6508, MYL6P2, RPS26P4, JCADP1, B3GALT5, B3GALT5-AS1, AF064860.1, AF064860.2, IGSF5, PCP4, DSCAM, MIR4760, DSCAM-AS1, AF064863.1, DSCAM-IT1, AF064866.1, YRDCP3, AL773573.1, LINC00323, MIR3197, BACE2, PLAC4, BACE2-IT1, FAM3B, MX2, MX1, AP001610.2.

Autosomal genes at a single copy (total copy number 1): 5,943. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
